HCMI case HCM-BROD-1102-C85 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Malignant Lymphomas, NOS or Diffuse; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a2e9805f-e36a-46c1-b36c-fc064848501c

Demographics
Sex at birth: male; Race: white; Year of birth: 1936; Vital status: Dead; Days to death: 1,623 days (4.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant lymphoma, non-Hodgkin, NOS: ICD-O-3 morphology code: 9591/3; ICD-10 code: C85.9; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 74.0 years (27,039 days); Prior treatment: Yes.
   Pathology details: Additional pathology findings: Percent follicular component > 10%; Bone marrow malignant cells: Yes; Lymph node involved site: Inguinal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride + Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,555 days (4.3 years); Days to treatment end: 1,571 days (4.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bendamustine; Treatment intent type: Neoadjuvant; Days to treatment start: 1,571 days (4.3 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Rituximab; Treatment intent type: Neoadjuvant; Days to treatment start: 1,575 days (4.3 years).
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,623 days (4.4 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 1,622.

Molecular and laboratory tests
- MYC rearrangement (FISH): Positive.
- Hemoglobin 8.7 g/dL.
- Platelets 9 ×10³/µL.
- Hematocrit 24%.
- Leukocytes 4.3 ×10³/µL.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-BROD-1102-C85-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
